Gene-level copy-number profile of tumor specimen C3N-03069-01 from CPTAC case C3N-03069, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 50.7 years (18,530 days).
Specimen C3N-03069-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1fb76c36-e5cc-44ab-8c15-61d53b106a1b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03069-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/0f527d9c-487e-48a4-8431-44dc6e867626

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 92; copy number 1: 8,241; copy number 2: 44,525; copy number 3: 4,266; copy number 4: 1,224; copy number 5: 31; copy number 6: 12; copy number 7: 1; copy number 12: 2.

Homozygous deletions (total copy number 0; autosomes only): 91 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:80,534,978–80,584,363, 1 gene (within-gene range 0–2): AL136234.1.
- chr3:28,315,003–28,349,050, 1 gene (within-gene range 0–2): AZI2.
- chr4:46,035,769–46,124,054, 1 gene: GABRG1.
- chr4:58,780,626–58,988,182, 2 genes (within-gene range 0–2): AC017091.1, LINC02619.
- chr6:49,960,249–49,969,625, 2 genes: DEFB114, DEFB113.
- chr9:12,685,439–12,710,285, 1 gene (within-gene range 0–1): TYRP1.
- chr9:20,999,509–26,118,408, 76 genes (broad region; genes not listed).
- chr10:26,931,206–26,944,418, 1 gene: FAM238C.
- chr11:48,880,111–48,885,237, 1 gene (within-gene range 0–2): AC027369.6.
- chr12:87,041,916–87,042,423, 1 gene: AC079597.1.
- chr15:35,372,256–35,401,768, 3 genes (within-gene range 0–1): MIR3942, AC019288.1, HNRNPA1P45.
- chr16:61,743,154–61,743,476, 1 gene (within-gene range 0–2): RN7SKP76.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 46 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:60,281,444–60,546,660, 1 gene, copy number 5: AC244258.1.
- chr8:145,052,465–145,066,685, 1 gene, copy number 7: C8orf33.
- chr9:63,974,762–64,082,534, 2 genes, copy number 12: AL163540.1, U6.
- chr14:18,333,726–18,419,273, 4 genes, copy number 6: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr15:62,082,450–62,083,305, 1 gene, copy number 5: NPM1P47.
- chr21:7,744,962–8,701,562, 29 genes, copy number 5: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1.
- chr21:10,521,553–13,067,033, 8 genes, copy number 6 (within-gene range 3–6): TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P.

Autosomal genes at a single copy (total copy number 1): 7,450. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
